Somatic mutation profile of tumor specimen C3N-08902-02 (aliquot CPT0495670010) from CPTAC case C3N-08902, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 47.0 years (17,174 days).
Specimen C3N-08902-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3c9227a-b55e-473e-8bed-7ea09dea1bfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-08902-31 (Blood Derived Normal), aliquot CPT0495760006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6912f499-603f-48cd-ba26-b6336e070b1b

The open-access MAF lists 397 somatic variants for this specimen: 247 protein-altering or splice-affecting, 136 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 136, Nonsense Mutation 13, Intron 7, Splice Region 4, Splice Site 3, Frame Shift Del 3, RNA 2, 5'Flank 2, 3'Flank 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4585C>T p.Q1529* | Nonsense Mutation (SNP) | VAF 61/318 reads (19%) | catalogued as rs1554085992, CM940073, COSV57326777; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/299 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA2 | c.4690C>T p.R1564W (on ENST00000614293; = p.R1534W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/442 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.78); catalogued as rs768174682; called by muse, mutect2, varscan2
- ACAN | c.4877C>T p.P1626L | Missense Mutation (SNP) | VAF 65/397 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs753824539, COSV61370296; called by muse, mutect2, varscan2
- ACRBP | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 87/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99976056; called by muse, mutect2, varscan2
- ADAD2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 154/676 reads (23%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs755711407; called by muse, mutect2, varscan2
- ADAM18 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs267601916, COSV55844457; called by muse, mutect2, varscan2
- ADCY8 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 102/486 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1367206133, COSV53904853; called by muse, mutect2, varscan2
- AMPD3 | c.646C>T p.P216S (on ENST00000396553 / NM_001025389.2; = p.P225S on NM_000480.3) | Missense Mutation (SNP) | VAF 68/337 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV67331484; called by muse, mutect2, varscan2
- ARAP2 | c.3217C>G p.Q1073E | Missense Mutation (SNP) | VAF 11/338 reads (3%) | SIFT tolerated (0.92); PolyPhen benign (0.027); catalogued as COSV58292774; called by muse, mutect2
- ATG2A | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs769160641, COSV101034464; called by muse, mutect2, varscan2
- BRWD1 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 43/359 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV60893751; called by muse, mutect2, varscan2
- C14orf39 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV100407843; called by muse, mutect2, varscan2
- CCKAR | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 37/532 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.649); catalogued as COSV99810381; called by muse, mutect2
- CD163L1 | c.1514G>A p.W505* | Nonsense Mutation (SNP) | VAF 94/474 reads (20%) | catalogued as COSV58022887; called by muse, mutect2, varscan2
- CDH8 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 96/556 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.148); catalogued as rs1567404075, COSV100180310; called by muse, mutect2
- CENATAC | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 14/338 reads (4%) | catalogued as rs1440820230; called by muse, mutect2
- CGB8 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 48/748 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1280203641; called by muse, varscan2
- CHKB | c.446C>A p.P149Q | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV56418398; called by muse, mutect2, varscan2
- COASY | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 92/375 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV99888275; called by muse, mutect2, varscan2
- CPED1 | c.2056-1G>A p.X686_splice | Splice Site (SNP) | VAF 73/253 reads (29%) | catalogued as rs1349297351, COSV60002683; called by muse, mutect2, varscan2
- CSMD1 | c.2198G>A p.G733E (on ENST00000520002; = p.G732E on NM_033225.6) | Missense Mutation (SNP) | VAF 78/355 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100148719, COSV59276812; called by muse, mutect2, varscan2
- CTNND2 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 65/361 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100476376; called by muse, mutect2, varscan2
- CYP11B2 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 72/522 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs773025558, COSV100011196, COSV59998195; called by muse, mutect2
- CYP2C18 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99608474; called by muse, mutect2, varscan2
- DCAF4 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 57/297 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62320234; called by muse, mutect2, varscan2
- DCLK1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs773115614, COSV55174788; called by muse, mutect2, varscan2
- DNAH7 | c.10872G>C p.Q3624H | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56783841; called by muse, mutect2, varscan2
- DNAH8 | c.2873G>A p.R958K | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV59473095; called by muse, mutect2
- DOCK4 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 72/383 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1429913463, COSV69854513; called by muse, mutect2, varscan2
- DOCK8 | c.6196C>T p.P2066S | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs749662746, COSV66623930; called by muse, mutect2, varscan2
- EFR3A | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1174181910, COSV54454132; called by muse, mutect2, varscan2
- EVPL | c.48_74del p.A20_P28del | In Frame Del (DEL) | VAF 52/295 reads (18%) | catalogued as rs754321569; called by mutect2, varscan2
- FCRL6 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100220427; called by muse, mutect2, varscan2
- FER1L6 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67549010; called by muse, mutect2, varscan2
- FHL5 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs868468680, COSV58739330; called by muse, mutect2, varscan2
- FSTL5 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60228052; called by muse, mutect2, varscan2
- GDF3 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 93/482 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs764970795; called by muse, mutect2, varscan2
- GJB6 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 58/383 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104384457; called by muse, mutect2, varscan2
- GLRA3 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99926948; called by muse, mutect2
- GPRC6A | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 28/403 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV100114223, COSV100114798; called by muse, mutect2
- GRID2IP | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.201); catalogued as rs1396145881; called by muse, mutect2, varscan2
- HAO1 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 37/310 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381766121; called by muse, mutect2, varscan2
- HPR | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs766844305, COSV57182620; called by muse, mutect2, varscan2
- HYDIN | c.4459G>A p.G1487R | Missense Mutation (SNP) | VAF 80/392 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748626665, COSV66830115; called by muse, mutect2
- IFT140 | c.3368C>T p.P1123L | Missense Mutation (SNP) | VAF 63/447 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781672845, COSV63697684; called by muse, mutect2, varscan2
- IL1R1 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52105577; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs747300297, COSV100147038, COSV56240747; called by muse, mutect2, varscan2
- IL31RA | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.853); catalogued as rs530684072; called by muse, mutect2, varscan2
- IMPG2 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.18); catalogued as COSV51985655; called by muse, mutect2, varscan2
- JAKMIP2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs765897999; called by muse, mutect2, varscan2
- KCNB2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 62/408 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs547685470, COSV73048891; called by muse, mutect2, varscan2
- KCTD5 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 42/298 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV57064069; called by muse, mutect2, varscan2
- KRT74 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV99977538; called by muse, mutect2, varscan2
- LAMA5 | c.10037C>T p.S3346F | Missense Mutation (SNP) | VAF 79/517 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.28); catalogued as COSV53375039; called by muse, mutect2, varscan2
- LAMB3 | c.3242T>G p.I1081R | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs771351792; called by muse, mutect2, varscan2
- LINGO4 | c.220G>C p.G74R | Missense Mutation (SNP) | VAF 84/499 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.786); catalogued as COSV59092803, COSV59094200; called by muse, mutect2
- LIPE | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54921680; called by muse, mutect2, varscan2
- LTF | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 122/448 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1221410280, COSV51605566; called by muse, mutect2, varscan2
- MADD | c.1436G>A p.G479D | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60620557; called by muse, mutect2, varscan2
- MAL2 | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 56/286 reads (20%) | catalogued as COSV52662020; called by muse, mutect2, varscan2
- MTUS2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 79/531 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1337599526; called by muse, mutect2, varscan2
- MUC15 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 60/351 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55554836; called by muse, mutect2, varscan2
- MUC16 | c.3349G>A p.E1117K | Missense Mutation (SNP) | VAF 75/379 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV67451931, COSV67491091, COSV67500653; called by muse, mutect2, varscan2
- MUC17 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 113/445 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs560174964, COSV60297386; called by muse, mutect2, varscan2
- MUC2 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1016796357; called by muse, mutect2, varscan2
- NAA25 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs968159653; called by muse, mutect2
- NCR2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 37/473 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as rs375146981; called by muse, mutect2
- NLRC5 | c.2195G>A p.S732N | Missense Mutation (SNP) | VAF 75/452 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs771824021; called by muse, mutect2, varscan2
- NUDT1 | c.313G>A p.D105N (on ENST00000397048 / NM_198952.1; = p.D82N on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV56127095; called by muse, mutect2, varscan2
- OGDHL | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs774306809, COSV65105065; called by muse, mutect2, varscan2
- OR10A6 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 91/414 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV59165080; called by muse, mutect2, varscan2
- OR4K13 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV59859738; called by muse, mutect2
- OR52B4 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 79/406 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs267602877, COSV68768715; called by muse, mutect2, varscan2
- OR8H1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 88/440 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV57294883; called by muse, mutect2, varscan2
- ORC5 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52403295; called by muse, mutect2, varscan2
- OSER1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs199780305; called by muse, mutect2, varscan2
- PAK5 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 42/363 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.282); catalogued as COSV62031570; called by muse, mutect2, varscan2
- PARP12 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54933776; called by muse, mutect2, varscan2
- PDE1C | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV100373567, COSV58506661; called by muse, mutect2, varscan2
- PDZD2 | c.2675G>A p.G892E | Missense Mutation (SNP) | VAF 82/403 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs772174791; called by muse, mutect2, varscan2
- PDZD2 | c.5224G>A p.E1742K | Missense Mutation (SNP) | VAF 74/414 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs202191557; called by muse, mutect2, varscan2
- PPIAL4G | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1407602581; called by muse, mutect2
- PPP1R3A | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 118/475 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV52885417; called by muse, mutect2, varscan2
- PPP4R4 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as COSV100429053; called by muse, mutect2, varscan2
- PRR18 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 38/634 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1054099396; called by muse, mutect2
- PSG6 | c.68del p.S23Yfs*3 | Frame Shift Del (DEL) | VAF 34/235 reads (14%) | catalogued as COSV51834884; called by mutect2, pindel, varscan2
- RAB43 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as rs549510648; called by muse, mutect2, varscan2
- REEP1 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 12/353 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV99383173; called by muse, mutect2
- RFX6 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.74); catalogued as rs1460911503; called by muse, mutect2, varscan2
- RGS9 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs755297304, COSV52224127; called by muse, mutect2, varscan2
- RNF166 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 65/332 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs765947541, COSV57190219; called by muse, mutect2, varscan2
- RORB | c.730G>A p.E244K (on ENST00000396204 / NM_001365023.1; = p.E233K on NM_006914.4) | Missense Mutation (SNP) | VAF 53/352 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV65336711; called by muse, mutect2, varscan2
- RTN4IP1 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs762946357; called by muse, mutect2
- SAGE1 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782783697; called by muse, mutect2, varscan2
- SALL3 | c.2924C>T p.P975L | Missense Mutation (SNP) | VAF 95/690 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1331463183, COSV73305915; called by muse, mutect2, varscan2
- SCN2A | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51836478; called by muse, mutect2, varscan2
- SHANK1 | c.6076G>T p.G2026* | Nonsense Mutation (SNP) | VAF 100/563 reads (18%) | catalogued as COSV53256703; called by muse, mutect2, varscan2
- SHANK2 | c.2872C>T p.R958C | Missense Mutation (SNP) | VAF 104/453 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs782128763, CM1512624; called by muse, mutect2, varscan2
- SIGLEC5 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as rs770008591; called by muse, mutect2, varscan2
- SLCO4C1 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.257); catalogued as COSV60513866, COSV60517155; called by muse, mutect2, varscan2
- SMIM33 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs751901162; called by muse, mutect2, varscan2
- SPAM1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.214); catalogued as COSV99773415; called by muse, mutect2, varscan2
- SPTA1 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs534906145, COSV63757502, COSV63762278; called by muse, mutect2, varscan2
- SPTBN4 | c.7165G>A p.G2389S | Missense Mutation (SNP) | VAF 86/590 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1391077474; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV59138613; called by muse, mutect2
- SYNDIG1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 85/511 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1273527923; called by muse, mutect2, varscan2
- TECTA | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV99881893; called by muse, mutect2, varscan2
- TENM4 | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53615438, COSV53669843; called by muse, mutect2, varscan2
- TNIP3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV104379542, COSV50253353; called by muse, mutect2, varscan2
- TRIM10 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 27/463 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1275146579; called by muse, mutect2
- UNC79 | c.539C>T p.S180L (on ENST00000393151 / NM_001346218.2; = p.S3L on NM_020818.5) | Missense Mutation (SNP) | VAF 101/475 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138265885, COSV56414101; called by muse, mutect2, varscan2
- UNKL | c.1421C>T p.S474L | Missense Mutation (SNP) | VAF 76/509 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as rs779895634; called by muse, mutect2, varscan2
- USH2A | c.11048G>A p.G3683E | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1558086029; called by muse, mutect2
- VAV3 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs151122345, COSV64065350; called by muse, mutect2
- VGLL3 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs1249235608, COSV67352483; called by muse, mutect2
- XKR9 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1000729653, COSV68772873; called by muse, mutect2, varscan2
- ZBTB24 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 78/397 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs781753593, COSV100018387; called by muse, mutect2, varscan2
- ZNF229 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 65/414 reads (16%) | catalogued as rs377446964, COSV52163535, COSV52165500; called by muse, mutect2, varscan2
- ZNF229 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs772104391, COSV52161646; called by muse, mutect2
- ZNF256 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1259628682; called by muse, mutect2, varscan2
- ZNF519 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV101645556; called by muse, mutect2, varscan2
- ZNF622 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 90/362 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1421421297; called by muse, mutect2, varscan2
- ZNRF4 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 85/546 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs751789942; called by muse, mutect2, varscan2
- A1BG | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 68/443 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- ABCB6 | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 34/531 reads (6%) | called by muse, mutect2
- ABCF1 | c.1324C>T p.P442S (on ENST00000326195 / NM_001025091.2; = p.P404S on NM_001090.3) | Missense Mutation (SNP) | VAF 36/572 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.18); called by muse, mutect2
- AC098582.1 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 29/423 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.4); called by muse, mutect2
- AKNAD1 | c.1772G>A p.R591K | Missense Mutation (SNP) | VAF 34/417 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- ALPK2 | c.6007G>A p.E2003K | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMER3 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 132/522 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ANGPT1 | c.1228G>T p.G410W | Missense Mutation (SNP) | VAF 70/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.3506G>A p.G1169D | Missense Mutation (SNP) | VAF 38/507 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK3 | c.1307C>A p.P436Q | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF11 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 53/390 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ASB4 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASL | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BRWD1 | c.1937A>C p.D646A | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BUB1 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 70/357 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CA9 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 97/612 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC81 | c.784G>A p.D262N (on ENST00000445632 / NM_001156474.2; = p.D172N on NM_021827.4) | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CD163 | c.2243G>T p.W748L | Missense Mutation (SNP) | VAF 90/429 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CDKN2A | c.311_324del p.L104Rfs*11 | Frame Shift Del (DEL) | VAF 80/651 reads (12%) | called by mutect2, pindel, varscan2
- CLASRP | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 77/601 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP2 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CNTNAP4 | c.2997G>A p.E999= | Splice Region (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- COL4A6 | c.1469A>G p.N490S | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTDSPL2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2
- CYP4X1 | c.177G>A p.K59= | Splice Region (SNP) | VAF 46/284 reads (16%) | called by muse, mutect2, varscan2
- DGKI | c.2782C>T p.H928Y | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DGKI | c.1500G>A p.W500* | Nonsense Mutation (SNP) | VAF 37/376 reads (10%) | called by muse, mutect2, varscan2
- DGKK | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DNAH10 | c.2891C>T p.P964L (on ENST00000409039; = p.P903L on NM_207437.3) | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- DSC2 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMCN | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 29/344 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- EPHB6 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 108/522 reads (21%) | called by muse, mutect2, varscan2
- EPYC | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ERICH3 | c.1764C>A p.H588Q | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ERICH6 | c.405T>C p.S135= | Splice Region (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- FAM236D | c.213G>A p.R71= (on ENST00000419795 / NM_001348203.1; = p.R67= on NM_001348202.1) | Splice Region (SNP) | VAF 51/243 reads (21%) | called by muse, mutect2, varscan2
- FPR2 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- FRAS1 | c.9529C>T p.H3177Y | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GFRAL | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- GINS1 | c.240-1G>A p.X80_splice | Splice Site (SNP) | VAF 30/248 reads (12%) | called by muse, mutect2, varscan2
- GLCE | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- GPC3 | c.576G>T p.L192F | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- GPR179 | c.7037G>A p.G2346D (on ENST00000621958; = p.G2345D on NM_001004334.4) | Missense Mutation (SNP) | VAF 88/436 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- GRID2IP | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GSS | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 73/384 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- HEPH | c.3189T>A p.F1063L (on ENST00000343002; = p.F796L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHLA1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 71/357 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- HYLS1 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 85/418 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IFT140 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- IGHV1OR15-9 | c.340T>G p.Y114D | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IKZF1 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 73/455 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- IL36B | c.444C>A p.D148E | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- ITGA10 | c.3461A>T p.K1154I | Missense Mutation (SNP) | VAF 22/359 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ITGA2B | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 94/439 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ITGB2 | c.2039C>T p.P680L (on ENST00000302347; = p.P656L on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/505 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITPR2 | c.2596C>T p.H866Y | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- KCNK10 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 105/556 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF21B | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 24/363 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- KLF18 | c.1361A>G p.N454S | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT tolerated, low confidence (0.29); called by muse, mutect2, varscan2
- KLF18 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 65/393 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, varscan2
- LINGO4 | c.218G>A p.W73* | Nonsense Mutation (SNP) | VAF 84/500 reads (17%) | called by muse, mutect2
- LMTK2 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 117/473 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMTK3 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, varscan2
- MAPK10 | c.761C>T p.P254L (on ENST00000359221 / NM_001351625.2; = p.P292L on NM_002753.5) | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2
- MAX | c.221_225del p.M74Kfs*11 | Frame Shift Del (DEL) | VAF 51/335 reads (15%) | called by mutect2, pindel, varscan2
- MEP1B | c.398T>C p.V133A | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- METRN | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 86/557 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MOV10 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MUC16 | c.29170A>G p.T9724A | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- MYBPC2 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH14 | c.4288G>A p.E1430K | Missense Mutation (SNP) | VAF 88/571 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MYH6 | c.5352G>A p.M1784I | Missense Mutation (SNP) | VAF 84/486 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYO7B | c.4521G>A p.M1507I | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.082); called by muse, mutect2
- NADSYN1 | c.1638C>A p.D546E | Missense Mutation (SNP) | VAF 45/270 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBEAL2 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 51/420 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBPF6 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- NLRP9 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NTPCR | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR11H4 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- OR13C2 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OTOF | c.3164C>T p.P1055L (on ENST00000272371 / NM_194248.3; = p.P308L on NM_004802.4) | Missense Mutation (SNP) | VAF 19/371 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTOL1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAGE2B | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCCB | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- PCDHAC1 | c.1761T>G p.D587E | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB2 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCSK9 | c.524-1G>A p.X175_splice | Splice Site (SNP) | VAF 29/205 reads (14%) | called by muse, mutect2, varscan2
- PDGFRA | c.1531A>G p.N511D | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2
- PEX13 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- PLEKHH1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- PLXDC2 | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PPP4R3A | c.2315C>T p.P772L (on ENST00000554943 / NM_001366432.1; = p.P759L on NM_001284280.1) | Missense Mutation (SNP) | VAF 87/488 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PRR14L | c.2873C>T p.S958L | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRSS33 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 36/282 reads (13%) | called by muse, mutect2, varscan2
- PTPN22 | c.2089C>T p.L697F (on ENST00000359785 / NM_001193431.2; = p.L642F on NM_012411.5) | Missense Mutation (SNP) | VAF 19/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PYHIN1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RBBP8NL | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2
- RGS11 | c.788C>T p.P263L (on ENST00000397770 / NM_183337.3; = p.P242L on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- SEC16A | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 42/337 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SEC23B | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SHC1 | c.797G>A p.G266E (on ENST00000368445 / NM_183001.5; = p.G156E on NM_003029.5) | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLAMF7 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC5A10 | c.1489C>T p.P497S (on ENST00000395645 / NM_001042450.4; = p.P513S on NM_152351.5) | Missense Mutation (SNP) | VAF 86/457 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPPL3 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRRM2 | c.5983C>T p.R1995* | Nonsense Mutation (SNP) | VAF 44/380 reads (12%) | called by muse, mutect2, varscan2
- STAB2 | c.2701T>G p.W901G | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- STIM1 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 75/392 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3287C>T p.S1096L | Missense Mutation (SNP) | VAF 76/359 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAS1R3 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 76/545 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TGFBR2 | c.461A>C p.N154T | Missense Mutation (SNP) | VAF 639/855 reads (75%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC18 | c.2965G>A p.A989T | Missense Mutation (SNP) | VAF 89/627 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNRC18 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 62/523 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAV8-1 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.32); called by muse, mutect2
- TTLL6 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.36786C>A p.N12262K (on ENST00000591111; = p.N4838K on NM_003319.4) | Missense Mutation (SNP) | VAF 32/417 reads (8%) | PolyPhen benign (0.426); called by muse, mutect2
- UNC13C | c.3513G>A p.M1171I | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- UTP14C | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 71/586 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WDR87 | c.5457G>A p.W1819* | Nonsense Mutation (SNP) | VAF 55/378 reads (15%) | called by muse, mutect2, varscan2
- ZNF2 | c.1142C>T p.P381L (on ENST00000611147 / NM_001291605.2; = p.P368L on NM_021088.4) | Missense Mutation (SNP) | VAF 39/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF492 | c.1577A>T p.N526I | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF786 | c.1201C>G p.H401D | Missense Mutation (SNP) | VAF 143/595 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF804B | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 40/397 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCA2 | c.4689C>T p.F1563= (on ENST00000614293; = p.F1533= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/442 reads (15%) | called by muse, mutect2, varscan2
- ACACA | c.6360T>C p.P2120= | Silent (SNP) | VAF 129/550 reads (23%) | called by muse, mutect2, varscan2
- ADSS1 | c.627C>T p.T209= | Silent (SNP) | VAF 46/403 reads (11%) | called by muse, mutect2, varscan2
- AK9 | c.4983C>T p.S1661= | Silent (SNP) | VAF 38/438 reads (9%) | called by muse, mutect2
- AKNAD1 | c.1773G>A p.R591= | Silent (SNP) | VAF 34/418 reads (8%) | catalogued as rs1210898599; called by muse, mutect2
- ALKBH2 | c.612G>A p.G204= | Silent (SNP) | VAF 96/379 reads (25%) | catalogued as COSV57450416; called by muse, mutect2, varscan2
- ANXA1 | c.993C>T p.T331= | Silent (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- ASXL3 | c.4536G>A p.Q1512= | Silent (SNP) | VAF 83/461 reads (18%) | catalogued as rs538610692, COSV52474710; called by muse, mutect2, varscan2
- ATP8B3 | c.3852C>T p.S1284= | Silent (SNP) | VAF 52/341 reads (15%) | called by muse, mutect2, varscan2
- BMP10 | c.1023C>T p.I341= | Silent (SNP) | VAF 100/432 reads (23%) | called by muse, mutect2, varscan2
- BTN2A1 | c.1323C>T p.L441= | Silent (SNP) | VAF 55/455 reads (12%) | called by muse, mutect2, varscan2
- BUB1 | c.1362C>T p.S454= | Silent (SNP) | VAF 70/356 reads (20%) | catalogued as rs750084498; called by muse, mutect2, varscan2
- BVES | c.645C>T p.F215= | Silent (SNP) | VAF 15/221 reads (7%) | catalogued as COSV58949301; called by muse, mutect2
- C19orf38 | c.141G>A p.A47= | Silent (SNP) | VAF 70/474 reads (15%) | catalogued as rs562091272; called by muse, mutect2, varscan2
- C20orf194 | c.3096C>T p.A1032= | Silent (SNP) | VAF 44/370 reads (12%) | called by muse, mutect2, varscan2
- C7orf61 | c.252G>A p.K84= | Silent (SNP) | VAF 153/540 reads (28%) | called by muse, mutect2, varscan2
- CCKAR | c.531C>T p.P177= | Silent (SNP) | VAF 36/529 reads (7%) | catalogued as COSV55163451; called by muse, mutect2
- CDH9 | c.1818C>T p.I606= | Silent (SNP) | VAF 68/357 reads (19%) | catalogued as COSV50318599; called by muse, mutect2, varscan2
- CHD7 | c.4086C>T p.F1362= | Silent (SNP) | VAF 64/368 reads (17%) | called by muse, mutect2, varscan2
- CIC | c.1644C>T p.A548= | Silent (SNP) | VAF 51/354 reads (14%) | catalogued as rs1428885445; called by muse, mutect2, varscan2
- CNGB3 | c.222C>T p.S74= | Silent (SNP) | VAF 40/253 reads (16%) | catalogued as COSV100182981; called by muse, mutect2, varscan2
- COL5A1 | c.5346C>T p.I1782= | Silent (SNP) | VAF 39/256 reads (15%) | called by muse, mutect2, varscan2
- CST4 | c.255C>T p.F85= | Silent (SNP) | VAF 76/375 reads (20%) | catalogued as rs759771891, COSV54149822; called by muse, mutect2, varscan2
- CSTF1 | c.1236C>T p.F412= | Silent (SNP) | VAF 60/436 reads (14%) | catalogued as rs781713453; called by muse, mutect2, varscan2
- CTU1 | c.222G>A p.L74= | Silent (SNP) | VAF 75/464 reads (16%) | catalogued as rs1248679628; called by muse, mutect2, varscan2
- CYP2C19 | c.1284C>T p.F428= | Silent (SNP) | VAF 33/221 reads (15%) | catalogued as rs1348954494, COSV100990580; called by muse, mutect2, varscan2
- CYP2D6 | c.705G>A p.A235= | Silent (SNP) | VAF 88/609 reads (14%) | catalogued as rs371769791; called by muse, mutect2, varscan2
- DAB1 | c.1047C>T p.L349= (on ENST00000371231; = p.L316= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 60/423 reads (14%) | catalogued as rs868749294; called by muse, mutect2, varscan2
- DCDC2C | c.507G>A p.T169= | Silent (SNP) | VAF 60/259 reads (23%) | catalogued as rs769575977; called by muse, mutect2
- DDX55 | c.810C>T p.H270= | Silent (SNP) | VAF 74/371 reads (20%) | called by muse, mutect2, varscan2
- DMTN | c.39G>A p.G13= | Silent (SNP) | VAF 56/354 reads (16%) | called by muse, mutect2, varscan2
- DNAH12 | c.1680A>G p.L560= | Silent (SNP) | VAF 32/220 reads (15%) | called by muse, mutect2, varscan2
- DSP | c.2077C>T p.L693= | Silent (SNP) | VAF 40/306 reads (13%) | called by muse, mutect2, varscan2
- DUSP6 | c.495G>A p.L165= | Silent (SNP) | VAF 29/532 reads (5%) | called by muse, mutect2
- EDAR | c.922C>T p.L308= | Silent (SNP) | VAF 61/305 reads (20%) | called by muse, mutect2, varscan2
- EIF4G1 | c.192C>T p.S64= | Silent (SNP) | VAF 36/426 reads (8%) | called by muse, mutect2
- EPHB6 | c.21C>T p.A7= | Silent (SNP) | VAF 108/515 reads (21%) | catalogued as rs779661993; called by muse, mutect2, varscan2
- EXOC4 | c.147A>G p.E49= | Silent (SNP) | VAF 49/473 reads (10%) | catalogued as rs1328129506; called by muse, mutect2, varscan2
- FAT1 | c.9519C>T p.S3173= | Silent (SNP) | VAF 17/246 reads (7%) | called by muse, mutect2
- FOXD2 | c.156C>T p.L52= | Silent (SNP) | VAF 78/480 reads (16%) | called by muse, varscan2
- FRMD5 | c.351C>T p.I117= | Silent (SNP) | VAF 37/248 reads (15%) | called by muse, mutect2, varscan2
- FRY | c.6360C>T p.L2120= | Silent (SNP) | VAF 47/295 reads (16%) | called by muse, mutect2, varscan2
- GABRB1 | c.528C>T p.T176= | Silent (SNP) | VAF 31/270 reads (11%) | catalogued as COSV99780566; called by muse, mutect2, varscan2
- GHRHR | c.801C>T p.F267= | Silent (SNP) | VAF 39/315 reads (12%) | catalogued as rs562517014, COSV58196515, COSV58197834; called by muse, mutect2, varscan2
- GPR176 | c.1002C>T p.T334= | Silent (SNP) | VAF 30/417 reads (7%) | called by muse, mutect2
- GPRIN1 | c.999C>G p.S333= | Silent (SNP) | VAF 61/396 reads (15%) | called by muse, mutect2, varscan2
- HHLA1 | c.1008G>A p.Q336= | Silent (SNP) | VAF 30/318 reads (9%) | called by muse, mutect2
- HLA-DPB1 | c.222C>T p.F74= | Silent (SNP) | VAF 97/700 reads (14%) | called by muse, mutect2, varscan2
- HSPH1 | c.1269C>T p.N423= | Silent (SNP) | VAF 41/341 reads (12%) | called by muse, mutect2, varscan2
- HTR3A | c.333C>T p.P111= | Silent (SNP) | VAF 12/358 reads (3%) | called by muse, mutect2
- IGSF1 | c.2289G>A p.E763= | Silent (SNP) | VAF 58/193 reads (30%) | called by muse, mutect2, varscan2
- IKZF3 | c.1395G>A p.V465= | Silent (SNP) | VAF 84/389 reads (22%) | catalogued as COSV53100581; called by muse, mutect2, varscan2
- INTU | c.2181C>T p.G727= | Silent (SNP) | VAF 51/328 reads (16%) | called by muse, mutect2, varscan2
- ITPR2 | c.2595C>T p.V865= | Silent (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.555G>A p.R185= | Silent (SNP) | VAF 58/295 reads (20%) | catalogued as COSV99508741; called by muse, mutect2, varscan2
- JMJD6 | c.903G>T p.T301= | Silent (SNP) | VAF 68/322 reads (21%) | catalogued as COSV100396337; called by mutect2, varscan2
- KCNB2 | c.84C>T p.I28= | Silent (SNP) | VAF 63/408 reads (15%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.585C>T p.I195= | Silent (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- KIAA1671 | c.741C>T p.F247= | Silent (SNP) | VAF 102/544 reads (19%) | called by muse, mutect2, varscan2
- KIAA1755 | c.3042C>T p.L1014= | Silent (SNP) | VAF 42/522 reads (8%) | catalogued as rs756657674, COSV54081241; called by muse, mutect2
- KIAA2012 | c.3054G>A p.Q1018= | Silent (SNP) | VAF 94/382 reads (25%) | catalogued as rs756781587; called by muse, mutect2, varscan2
- KLRC4 | c.213C>T p.L71= | Silent (SNP) | VAF 41/375 reads (11%) | called by muse, mutect2, varscan2
- KNOP1 | c.672C>T p.A224= | Silent (SNP) | VAF 50/385 reads (13%) | catalogued as rs1244297717; called by muse, mutect2, varscan2
- LPCAT4 | c.129G>A p.G43= | Silent (SNP) | VAF 32/323 reads (10%) | called by muse, mutect2
- LPIN3 | c.627C>T p.P209= | Silent (SNP) | VAF 48/287 reads (17%) | catalogued as rs1054503959; called by muse, mutect2, varscan2
- MAPK10 | c.762C>T p.P254= (on ENST00000359221 / NM_001351625.2; = p.P292= on NM_002753.5) | Silent (SNP) | VAF 20/486 reads (4%) | catalogued as COSV100175181; called by muse, mutect2
- MEGF8 | c.8112C>T p.F2704= (on ENST00000251268 / NM_001271938.2; = p.F2637= on NM_001410.3) | Silent (SNP) | VAF 51/481 reads (11%) | catalogued as rs761615916, COSV52098354; called by muse, mutect2, varscan2
- MEST | c.606C>T p.P202= | Silent (SNP) | VAF 44/384 reads (11%) | called by muse, mutect2, varscan2
- MOSMO | c.180G>A p.R60= | Silent (SNP) | VAF 58/580 reads (10%) | catalogued as rs566186097; called by muse, mutect2
- MRGPRX1 | c.822C>T p.F274= | Silent (SNP) | VAF 97/463 reads (21%) | catalogued as rs866353263, COSV57105708; called by muse, mutect2, varscan2
- MRGPRX2 | c.630C>T p.L210= | Silent (SNP) | VAF 14/436 reads (3%) | called by muse, mutect2
- MUC12 | c.10155A>G p.E3385= (on ENST00000379442; = p.E3242= on NM_001164462.1) | Silent (SNP) | VAF 190/4302 reads (4%) | called by muse, mutect2
- MUC16 | c.20763C>T p.S6921= | Silent (SNP) | VAF 61/406 reads (15%) | catalogued as COSV101202229; called by muse, mutect2, varscan2
- MYLK | c.156C>T p.F52= | Silent (SNP) | VAF 35/219 reads (16%) | catalogued as rs200095645, COSV60604762; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO15A | c.1089C>T p.P363= | Silent (SNP) | VAF 80/413 reads (19%) | called by muse, mutect2, varscan2
- MYO5B | c.315C>T p.I105= | Silent (SNP) | VAF 34/219 reads (16%) | catalogued as rs748097712, COSV53215610, COSV53227808; called by muse, mutect2, varscan2
- NEB | c.13698G>A p.L4566= | Silent (SNP) | VAF 27/369 reads (7%) | called by muse, mutect2
- NEUROD4 | c.453G>A p.G151= | Silent (SNP) | VAF 98/491 reads (20%) | catalogued as COSV99669971; called by muse, mutect2, varscan2
- NLRX1 | c.1431C>T p.F477= | Silent (SNP) | VAF 97/454 reads (21%) | catalogued as rs1565829149; called by muse, mutect2, varscan2
- NRCAM | c.2985A>T p.T995= (on ENST00000379028 / NM_001371124.1; = p.T979= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 29/284 reads (10%) | called by muse, mutect2, varscan2
- NRROS | c.1695C>T p.L565= | Silent (SNP) | VAF 54/327 reads (17%) | called by muse, mutect2, varscan2
- NT5DC4 | c.1065G>A p.L355= | Silent (SNP) | VAF 58/278 reads (21%) | called by muse, mutect2, varscan2
- OR10X1 | c.729G>A p.R243= | Silent (SNP) | VAF 54/356 reads (15%) | catalogued as COSV63767233; called by muse, mutect2, varscan2
- OR56A1 | c.303C>T p.F101= | Silent (SNP) | VAF 22/434 reads (5%) | called by muse, mutect2
- OR6C1 | c.132C>T p.I44= | Silent (SNP) | VAF 28/444 reads (6%) | catalogued as rs1426393595, COSV65573634, COSV65574530; called by muse, mutect2
- OR8K3 | c.391C>T p.L131= | Silent (SNP) | VAF 88/553 reads (16%) | catalogued as COSV57131456; called by muse, mutect2, varscan2
- PACS2 | c.564C>T p.A188= | Silent (SNP) | VAF 52/421 reads (12%) | catalogued as rs370519258; called by muse, mutect2, varscan2
- PAPPA2 | c.657C>T p.F219= | Silent (SNP) | VAF 26/395 reads (7%) | catalogued as COSV100867068; called by muse, mutect2
- PAPSS1 | c.1860C>T p.S620= | Silent (SNP) | VAF 35/218 reads (16%) | called by muse, mutect2, varscan2
- PCNT | c.5316G>A p.Q1772= | Silent (SNP) | VAF 81/456 reads (18%) | called by muse, mutect2, varscan2
- PDCD11 | c.3147C>T p.T1049= | Silent (SNP) | VAF 66/384 reads (17%) | called by muse, mutect2, varscan2
- PDZD2 | c.4335G>A p.Q1445= | Silent (SNP) | VAF 93/457 reads (20%) | called by muse, mutect2, varscan2
- PGK2 | c.525C>T p.S175= | Silent (SNP) | VAF 50/372 reads (13%) | catalogued as COSV100505748; called by muse, mutect2, varscan2
- PLEKHG5 | c.1764G>A p.V588= (on ENST00000400915 / NM_001042663.3; = p.V551= on NM_020631.6) | Silent (SNP) | VAF 28/462 reads (6%) | catalogued as COSV61068471; called by muse, mutect2
- PLEKHM2 | c.2973C>T p.F991= | Silent (SNP) | VAF 38/403 reads (9%) | catalogued as rs745838157, COSV53816048, COSV53816109; called by muse, mutect2, varscan2
- PLEKHN1 | c.1347G>A p.R449= (on ENST00000379409; = p.R397= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/404 reads (15%) | called by muse, mutect2, varscan2
- PORCN | c.1203C>T p.L401= (on ENST00000326194 / NM_203475.3; = p.L390= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/218 reads (30%) | called by muse, mutect2, varscan2
- PREB | c.792C>T p.L264= | Silent (SNP) | VAF 99/460 reads (22%) | called by muse, mutect2, varscan2
- PRSS33 | c.681C>T p.C227= | Silent (SNP) | VAF 33/267 reads (12%) | called by muse, varscan2
- PTK2B | c.2749C>T p.L917= | Silent (SNP) | VAF 63/310 reads (20%) | catalogued as COSV57762318, COSV57766192; called by muse, mutect2
- PTN | c.387C>A p.A129= | Silent (SNP) | VAF 27/499 reads (5%) | catalogued as COSV100780791; called by muse, mutect2
- RANBP2 | c.5163C>T p.F1721= | Silent (SNP) | VAF 31/589 reads (5%) | called by muse, mutect2
- RASGRP2 | c.762C>T p.S254= | Silent (SNP) | VAF 59/302 reads (20%) | called by muse, mutect2, varscan2
- RHCG | c.21C>T p.L7= | Silent (SNP) | VAF 16/291 reads (5%) | called by muse, mutect2
- RPL13 | c.453C>A p.T151= | Silent (SNP) | VAF 87/442 reads (20%) | called by muse, mutect2, varscan2
- S1PR1 | c.975C>T p.I325= | Silent (SNP) | VAF 38/430 reads (9%) | catalogued as COSV59513044; called by muse, mutect2
- SALL1 | c.2445G>A p.E815= | Silent (SNP) | VAF 63/386 reads (16%) | called by muse, mutect2, varscan2
- SLC16A14 | c.762G>A p.G254= | Silent (SNP) | VAF 95/489 reads (19%) | catalogued as rs1036258383; called by muse, mutect2, varscan2
- SLC37A2 | c.327G>A p.G109= | Silent (SNP) | VAF 17/214 reads (8%) | catalogued as rs1222218254; called by muse, mutect2
- SLC45A4 | c.1968C>T p.S656= (on ENST00000517878 / NM_001286646.2; = p.S605= on NM_001080431.2) | Silent (SNP) | VAF 55/404 reads (14%) | called by muse, mutect2, varscan2
- SOCS6 | c.852C>T p.S284= | Silent (SNP) | VAF 58/459 reads (13%) | catalogued as rs200886437; called by muse, mutect2, varscan2
- SPAM1 | c.351G>A p.K117= | Silent (SNP) | VAF 107/460 reads (23%) | catalogued as COSV56142618; called by muse, mutect2, varscan2
- SPATA6 | c.1371C>T p.S457= | Silent (SNP) | VAF 65/381 reads (17%) | catalogued as rs867306075; called by muse, mutect2, varscan2
- SPG11 | c.1167G>A p.Q389= | Silent (SNP) | VAF 34/324 reads (10%) | catalogued as rs1363553402; called by muse, mutect2
- SYNE1 | c.15483C>T p.A5161= (on ENST00000367255 / NM_182961.4; = p.A5090= on NM_033071.3) | Silent (SNP) | VAF 26/240 reads (11%) | catalogued as rs1035249484, COSV99557482; called by muse, mutect2, varscan2
- TAS2R60 | c.480C>T p.F160= | Silent (SNP) | VAF 43/450 reads (10%) | catalogued as COSV60330064; called by muse, mutect2, varscan2
- TBC1D22B | c.117C>T p.F39= | Silent (SNP) | VAF 27/205 reads (13%) | catalogued as COSV100996864; called by muse, mutect2, varscan2
- TCP11X2 | c.1371G>A p.K457= | Silent (SNP) | VAF 9/82 reads (11%) | called by mutect2, varscan2
- TENM3 | c.6255C>T p.G2085= | Silent (SNP) | VAF 83/421 reads (20%) | catalogued as rs1264670497; called by muse, mutect2, varscan2
- TENT5D | c.1020C>A p.P340= | Silent (SNP) | VAF 50/227 reads (22%) | catalogued as COSV57637388; called by muse, mutect2, varscan2
- TEX13C | c.1135C>T p.L379= | Silent (SNP) | VAF 63/261 reads (24%) | called by muse, mutect2, varscan2
- TMA16 | c.135C>A p.A45= | Silent (SNP) | VAF 45/285 reads (16%) | called by muse, mutect2, varscan2
- TREH | c.603G>A p.L201= | Silent (SNP) | VAF 112/369 reads (30%) | catalogued as rs782308579; called by muse, mutect2, varscan2
- TRIM10 | c.1425C>T p.S475= | Silent (SNP) | VAF 27/459 reads (6%) | called by muse, mutect2
- TRPC6 | c.1623C>T p.F541= | Silent (SNP) | VAF 58/330 reads (18%) | catalogued as COSV60260953; called by muse, mutect2, varscan2
- UNC13D | c.2392C>T p.L798= | Silent (SNP) | VAF 69/272 reads (25%) | catalogued as rs1440447746, COSV52883635; called by muse, mutect2, varscan2
- VIPR2 | c.315C>T p.F105= | Silent (SNP) | VAF 51/450 reads (11%) | catalogued as rs186398445, COSV51103495; called by muse, mutect2, varscan2
- VWA1 | c.945G>T p.S315= | Silent (SNP) | VAF 87/537 reads (16%) | called by muse, mutect2, varscan2
- ZNF385D | c.1098C>T p.F366= | Silent (SNP) | VAF 42/349 reads (12%) | catalogued as rs1401372402, COSV55765538; called by muse, mutect2, varscan2
- ZNF492 | c.1578T>C p.N526= | Silent (SNP) | VAF 15/217 reads (7%) | catalogued as rs775489050; called by muse, mutect2
- ZNF623 | c.426G>A p.R142= | Silent (SNP) | VAF 112/614 reads (18%) | called by muse, mutect2
- ZNF722P | c.15G>A p.P5= | Silent (SNP) | VAF 42/363 reads (12%) | catalogued as rs894100262; called by muse, mutect2, varscan2
- ZNF727 | c.156G>A p.L52= | Silent (SNP) | VAF 23/257 reads (9%) | called by muse, mutect2
- ZNF804A | c.2994C>T p.I998= | Silent (SNP) | VAF 79/368 reads (21%) | catalogued as COSV56437286; called by muse, mutect2, varscan2
- ZSCAN5B | c.1167G>A p.R389= | Silent (SNP) | VAF 51/391 reads (13%) | called by muse, mutect2, varscan2
- ZXDB | c.766C>T p.L256= | Silent (SNP) | VAF 74/275 reads (27%) | called by muse, mutect2, varscan2
- ALKBH6 | c.-126G>A | 5'UTR (SNP) | VAF 51/434 reads (12%) | called by muse, mutect2, varscan2
- CCDC107 | chr9:35657822 T>C | 5'Flank (SNP) | VAF 49/399 reads (12%) | catalogued as rs773432147; called by muse, mutect2, varscan2
- DCHS2 | n.568C>T | RNA (SNP) | VAF 35/343 reads (10%) | called by muse, mutect2, varscan2
- GPR68 | c.*399G>A | 3'UTR (SNP) | VAF 71/312 reads (23%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-4492C>T | Intron (SNP) | VAF 28/195 reads (14%) | called by muse, mutect2, varscan2
- MICAL3 | c.2605+120C>T | Intron (SNP) | VAF 72/521 reads (14%) | called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442594 G>A | 3'Flank (SNP) | VAF 26/262 reads (10%) | catalogued as rs752914996, COSV62633991; called by muse, mutect2
- NCAM1 | c.1090-414G>A | Intron (SNP) | VAF 54/322 reads (17%) | called by muse, varscan2
- NPAP1L | n.522C>T | RNA (SNP) | VAF 52/259 reads (20%) | catalogued as rs1348229468; called by muse, mutect2, varscan2
- OSBPL9 | c.319-15540T>A | Intron (SNP) | VAF 49/382 reads (13%) | called by muse, mutect2, varscan2
- SH2B2 | chr7:102281899 C>T | 5'Flank (SNP) | VAF 54/331 reads (16%) | called by muse, mutect2, varscan2
- TFPI | c.628+5406C>T | Intron (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- TOR1AIP2 | c.-147+12108T>G | Intron (SNP) | VAF 45/321 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.10360+4488G>A | Intron (SNP) | VAF 26/362 reads (7%) | catalogued as COSV60343261; called by muse, mutect2
